Somatic mutation profile of tumor specimen TCGA-85-7697-01A (aliquot TCGA-85-7697-01A-11D-2122-08) from TCGA case TCGA-85-7697, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 49.1 years (17,921 days).
Specimen TCGA-85-7697-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e156ae59-36c2-4bff-947f-36267245c5e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-7697-10A (Blood Derived Normal), aliquot TCGA-85-7697-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f78320e8-92cc-4a77-ac07-d2461af5b931

The open-access MAF lists 291 somatic variants for this specimen: 211 protein-altering or splice-affecting, 71 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 71, Nonsense Mutation 10, Frame Shift Del 9, Intron 4, RNA 3, Splice Site 2, Frame Shift Ins 2, 3'UTR 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.532del p.H178Tfs*69 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | catalogued as rs786202525, CD983489, CM111332, COSV52693338, COSV52783253, COSV52816064; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.8374G>T p.D2792Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV101446900, COSV71295202; called by muse, mutect2, varscan2
- ABCG4 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0.019); catalogued as rs1182985058, COSV56644268; called by muse, mutect2, varscan2
- ADAMTS20 | c.110T>A p.L37Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101239125; called by muse, mutect2, varscan2
- ADCY2 | c.2344G>T p.A782S | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV100602445, COSV57897991; called by muse, mutect2, varscan2
- ADGRE1 | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as COSV99165163; called by muse, mutect2, varscan2
- ADGRG3 | c.1385G>T p.R462L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV100342238; called by muse, mutect2, varscan2
- ADGRL2 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 32/124 reads (26%) | catalogued as COSV54691272; called by muse, mutect2, varscan2
- ADGRL4 | c.1029C>A p.N343K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs188452531, COSV100875821, COSV66066793; called by muse, mutect2, varscan2
- ALB | c.696A>C p.E232D | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99891165; called by muse, mutect2
- ANKAR | c.2894T>C p.V965A | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV55612045; called by muse, mutect2
- ANKLE2 | c.2144G>C p.R715T | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs764984991, COSV100514045; called by muse, mutect2, varscan2
- ANTXR1 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100362239; called by muse, mutect2
- ARHGDIB | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99967320; called by muse, mutect2, varscan2
- BRCA2 | c.6523G>C p.E2175Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs876658412, COSV66463236; ClinVar: uncertain significance; called by muse, mutect2
- BTN3A2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs774256825, COSV62686837; called by muse, mutect2, varscan2
- BZW1 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.612); catalogued as COSV100729836; called by muse, mutect2
- C4BPA | c.567A>T p.E189D | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV100891181; called by muse, mutect2, varscan2
- C9 | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444808446, COSV99661947; called by muse, mutect2, varscan2
- CACNA1A | c.3441C>G p.S1147R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as rs746195332, COSV100801898, COSV64190399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBL | c.1912G>T p.G638* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99876023; called by muse, mutect2, varscan2
- CCDC172 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV100319715; called by muse, mutect2, varscan2
- CCDC33 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100351192, COSV58350585; called by muse, mutect2
- CCDC38 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs754135929, COSV100717507, COSV60182809; called by muse, mutect2, varscan2
- CCDC60 | c.1515G>C p.W505C | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100554908; called by muse, mutect2
- CD5L | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as rs376778996; called by muse, mutect2, varscan2
- CDC7 | c.1201G>A p.G401S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52311039, COSV99319661; called by muse, mutect2, varscan2
- CDKN2A | c.304del p.A102Rfs*44 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs774904310, CM056559, COSV58704200, COSV58708391; called by mutect2, pindel
- CFAP47 | c.1924C>T p.L642F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs774189622, COSV99934814; called by muse, mutect2, varscan2
- CHIA | c.1271C>T p.S424L (on ENST00000343320; = p.S316L on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs754393219, COSV58475780; called by muse, mutect2, varscan2
- CHSY3 | c.1664T>A p.V555E | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100518842, COSV100518886; called by muse, mutect2, varscan2
- CIC | c.2228A>T p.H743L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as COSV99359351; called by muse, mutect2, varscan2
- CNTLN | c.1319G>T p.S440I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV99263563; called by muse, mutect2, varscan2
- COL12A1 | c.5018G>A p.G1673E | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV100485735; called by muse, mutect2
- CROT | c.1576A>G p.T526A | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV58974133; called by muse, mutect2, varscan2
- CRYGA | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100378360, COSV100378675; called by muse, mutect2
- CSMD2 | c.7909C>A p.R2637S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as rs768845179, COSV53917194, COSV99588418; called by muse, mutect2, varscan2
- CSMD3 | c.10651C>G p.R3551G (on ENST00000297405 / NM_001363185.1; = p.R3382G on NM_052900.3) | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV52118225, COSV99830646, COSV99853569; called by muse, mutect2, varscan2
- CSMD3 | c.7550G>A p.G2517E (on ENST00000297405 / NM_001363185.1; = p.G2413E on NM_052900.3) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52296351, COSV99830648; called by muse, mutect2, varscan2
- DEFB125 | c.280T>A p.S94T | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV101217499; called by muse, mutect2, varscan2
- DMD | c.352T>A p.W118R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM111773, COSV99921180; called by muse, mutect2, varscan2
- DOCK10 | c.2773G>C p.V925L | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99288761; called by muse, mutect2
- DPP6 | c.1651C>A p.L551M (on ENST00000377770 / NM_001364500.2; = p.L489M on NM_001936.5) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100124471; called by muse, mutect2
- DVL3 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100493586; called by muse, mutect2, varscan2
- DYSF | c.3262G>T p.A1088S | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV99245867; called by muse, mutect2, varscan2
- E2F8 | c.53T>C p.M18T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100001425; called by muse, mutect2, varscan2
- EHBP1L1 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); catalogued as rs372711295; called by muse, varscan2
- EPB41L1 | c.2054C>T p.S685F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV99149881; called by muse, mutect2, varscan2
- EPB41L5 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99758523; called by muse, mutect2
- ERICH3 | c.3424G>T p.G1142W | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100443921; called by muse, mutect2, varscan2
- ESX1 | c.513A>T p.R171S | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV101006425; called by muse, mutect2, varscan2
- EYS | c.1690C>A p.L564M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV100676206; called by muse, mutect2, varscan2
- FAM13A | c.1853C>A p.P618H | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as rs1445810823, COSV99983286; called by muse, mutect2, varscan2
- FANCM | c.5665A>C p.S1889R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99950848; called by muse, mutect2
- FBXW10 | c.2046G>C p.Q682H | Missense Mutation (SNP) | VAF 6/153 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100111325; called by muse, mutect2
- FBXW7 | c.1370T>A p.L457* (on ENST00000281708 / NM_001349798.2; = p.L377* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 83/219 reads (38%) | catalogued as COSV99655973; called by muse, mutect2, varscan2
- FCRL3 | c.717G>T p.W239C | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as COSV100943019; called by muse, mutect2
- FCRL5 | c.2047C>A p.L683M | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV100708761; called by muse, mutect2, varscan2
- FCRL5 | c.623C>A p.T208N | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100708762; called by muse, mutect2
- FRY | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100969038, COSV66577517; called by muse, mutect2
- FSIP1 | c.1735A>G p.K579E | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as rs1456404585, COSV99527794; called by muse, mutect2, varscan2
- GABRG2 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1363015660, COSV100729637; called by muse, mutect2
- GGH | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as COSV99478812; called by muse, mutect2, varscan2
- GOLGA3 | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.046); catalogued as rs1378453772, COSV99202583; called by muse, mutect2, varscan2
- GPR158 | c.2230C>T p.R744W | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1157039977, COSV66265734; called by muse, mutect2
- GPRASP1 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 34/93 reads (37%) | catalogued as COSV100850963; called by muse, mutect2, varscan2
- GUCA1C | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99225662, COSV99226028; called by muse, mutect2, varscan2
- HEATR3 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.259); catalogued as COSV99589842; called by muse, mutect2, varscan2
- HEY2 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64240122; called by muse, mutect2, varscan2
- HTR1F | c.617G>T p.R206I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.15); catalogued as COSV100138012, COSV60390743; called by muse, mutect2, varscan2
- IFT80 | c.1879A>G p.N627D | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100424604; called by muse, mutect2
- INSM2 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs369614424; called by muse, mutect2, varscan2
- KCNA4 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100068799, COSV60253634; called by muse, mutect2, varscan2
- KIF1B | c.2632G>T p.D878Y (on ENST00000377086 / NM_001365952.1; = p.D832Y on NM_015074.3) | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55816458, COSV99822986; called by muse, varscan2
- KIF2B | c.1943A>G p.K648R | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99275094; called by muse, mutect2
- KRT25 | c.88T>A p.F30I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100379879; called by muse, mutect2, varscan2
- L1TD1 | c.1692G>C p.M564I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100776558; called by muse, mutect2, varscan2
- LRP5 | c.1702A>G p.I568V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV99591741; called by muse, mutect2, varscan2
- LRRC4C | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762719989, COSV99537714; called by muse, mutect2, varscan2
- LY75 | c.110C>G p.T37S | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99716280; called by muse, mutect2
- MAGEA8 | c.309C>A p.H103Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99674497; called by muse, mutect2, varscan2
- MAGEB6 | c.364T>A p.S122T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100983708; called by muse, mutect2, varscan2
- MAGEC1 | c.1500G>T p.E500D | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as COSV99595376; called by muse, mutect2, varscan2
- MAGEC3 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1180243991, COSV100025176; called by muse, mutect2, varscan2
- MAP2 | c.2691C>A p.Y897* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV52301483, COSV99559104; called by mutect2, varscan2
- MAST3 | c.1712A>G p.Y571C | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99444834; called by muse, mutect2, varscan2
- MORC1 | c.2892A>C p.K964N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.076); catalogued as COSV99225663; called by muse, mutect2
- MORC1 | c.2890A>T p.K964* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99225666; called by muse, mutect2
- MORC1 | c.1015C>A p.L339I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV51714121, COSV99225669; called by muse, mutect2, varscan2
- MPEG1 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV99915226; called by muse, mutect2, varscan2
- MROH9 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV100882706, COSV100882731; called by muse, mutect2
- MSR1 | c.293C>A p.T98K | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.025); catalogued as COSV100026916, COSV50516677; called by muse, mutect2, varscan2
- MST1R | c.3631G>A p.A1211T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1379154922, COSV99618366; called by muse, mutect2, varscan2
- MUC16 | c.2843T>A p.M948K | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV101199318; called by muse, mutect2
- MUC3A | c.8368G>A p.D2790N | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.151); catalogued as COSV100114369; called by muse, mutect2
- MYBPC3 | c.2452T>C p.W818R | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99920164; called by muse, mutect2, varscan2
- MYO1F | c.251C>G p.P84R | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM090125, COSV100596545, COSV57792734; called by muse, mutect2, varscan2
- MYO3A | c.4787C>G p.P1596R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs758223666, COSV99392995; called by muse, mutect2, varscan2
- NAALAD2 | c.1005T>A p.H335Q | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100428289; called by muse, mutect2
- NAV3 | c.3215G>T p.G1072V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as rs1211789032, COSV99889225; called by muse, mutect2, varscan2
- NAV3 | c.5648G>T p.G1883V (on ENST00000397909 / NM_001024383.2; = p.G1861V on NM_014903.6) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99889227; called by muse, mutect2, varscan2
- NDST2 | c.1845G>A p.G615= | Splice Region (SNP) | VAF 15/89 reads (17%) | catalogued as COSV100013831; called by muse, mutect2, varscan2
- NECAB1 | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.143); catalogued as COSV70243484; called by muse, mutect2
- NFIA | c.984G>C p.K328N | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100963619; called by muse, mutect2, varscan2
- NLRP5 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV101173530; called by muse, mutect2, varscan2
- NPC1L1 | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.263); catalogued as COSV56928807, COSV99204538; called by muse, varscan2
- OASL | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462175311, COSV99984492; called by muse, mutect2, varscan2
- OLR1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.32); catalogued as COSV100376350; called by muse, mutect2, varscan2
- OR1S2 | c.454A>T p.R152W | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV100224089; called by muse, mutect2, varscan2
- OR2T4 | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV100822444; called by muse, mutect2, varscan2
- OR4C6 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV100051526, COSV100051727; called by muse, mutect2, varscan2
- OR4K5 | c.366G>C p.R122S | Missense Mutation (SNP) | VAF 40/552 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100262277; called by muse, mutect2
- OR52N2 | c.149T>A p.L50H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100396086; called by muse, mutect2, varscan2
- OR6K2 | c.908A>G p.K303R | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.028); catalogued as COSV100656752; called by muse, mutect2
- OR6Q1 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV100109711; called by muse, mutect2, varscan2
- PABPC1L | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV99407698; called by muse, mutect2, varscan2
- PAG1 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV99597266; called by muse, mutect2, varscan2
- PCDH11X | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100010677; called by muse, mutect2, varscan2
- PCDHA2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.309); catalogued as COSV100973770; called by muse, mutect2, varscan2
- PCDHGA12 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 5/94 reads (5%) | catalogued as COSV99339276; called by muse, mutect2
- PCNT | c.2127A>C p.E709D | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100855336; called by muse, mutect2
- PCSK5 | c.668C>G p.A223G | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100949781, COSV65089753; called by muse, mutect2, varscan2
- PDLIM5 | c.769A>G p.S257G | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.379); catalogued as COSV100523512; called by muse, mutect2, varscan2
- PEX1 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV99952024; called by muse, mutect2, varscan2
- PGBD4 | c.718G>C p.V240L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.173); catalogued as COSV99854788; called by muse, mutect2
- PIK3R5 | c.2099C>A p.S700Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99353150; called by muse, mutect2
- PKDREJ | c.5420T>C p.L1807P | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs1391610267, COSV99478675; called by muse, mutect2, varscan2
- PLG | c.1055G>T p.C352F | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99804514; called by muse, varscan2
- PLXNC1 | c.2068G>T p.A690S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV99312843; called by muse, mutect2, varscan2
- PNLIPRP2 | c.143C>A p.S48Y | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100077694; called by muse, mutect2, varscan2
- PNPLA7 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs757659216, COSV52999113; called by muse, mutect2, varscan2
- PPM1N | c.857C>A p.A286E | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV99838838; called by muse, mutect2, varscan2
- PPP1R17 | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as rs141313463, COSV100566332; called by muse, mutect2, varscan2
- PPP1R32 | c.322C>A p.R108S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100087753, COSV58546299; called by muse, mutect2, varscan2
- PRKDC | c.5317G>A p.V1773I | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100039667; called by muse, mutect2, varscan2
- PRKG1 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100907225; called by muse, mutect2, varscan2
- PRSS16 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 20/170 reads (12%) | catalogued as COSV100041650; called by muse, mutect2, varscan2
- PSG1 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as COSV99739503; called by muse, mutect2, varscan2
- PTGER3 | c.1075C>A p.Q359K | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.733); catalogued as COSV100138631; called by muse, mutect2, varscan2
- RAB3GAP2 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV99424609; called by muse, mutect2, varscan2
- RAG2 | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100271209; called by mutect2, varscan2
- RANGAP1 | c.1148A>T p.D383V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV100663729; called by muse, mutect2, varscan2
- RAPGEF5 | c.701G>C p.R234T (on ENST00000401957 / NM_001367602.2; = p.R537T on NM_012294.5) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.358); catalogued as COSV100686827; called by muse, mutect2, varscan2
- RIOK3 | c.1344G>T p.Q448H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.421); catalogued as COSV100259258; called by muse, mutect2, varscan2
- RNH1 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs867719923, COSV100339090; called by muse, mutect2
- RP1L1 | c.2090A>T p.Q697L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101223128; called by muse, mutect2, varscan2
- SAMD3 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV100148176; called by muse, mutect2, varscan2
- SAMD7 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100156853; called by muse, mutect2, varscan2
- SCN2A | c.3046T>A p.F1016I | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99330982; called by muse, mutect2, varscan2
- SDK1 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101269134; called by muse, mutect2, varscan2
- SEMA5B | c.850+1G>T p.X284_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99531368; called by muse, mutect2, varscan2
- SEMA6B | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100014767; called by muse, mutect2, varscan2
- SHPRH | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV99261816; called by muse, mutect2, varscan2
- SLAMF6 | c.239C>A p.P80Q | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100924864, COSV63587736; called by muse, mutect2, varscan2
- SLC17A3 | c.1172C>G p.A391G | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as COSV100645309; called by muse, mutect2, varscan2
- SLC7A3 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs766677040, COSV99979484; called by muse, mutect2, varscan2
- SLCO1B1 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs1393757524, COSV99918256; called by muse, mutect2, varscan2
- SLCO1C1 | c.878G>T p.W293L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV99858855; called by muse, mutect2, varscan2
- SLCO1C1 | c.879G>T p.W293C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.289); catalogued as COSV99858858; called by muse, mutect2, varscan2
- SNAPC4 | c.827G>A p.S276N | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as COSV100047077; called by muse, mutect2, varscan2
- SORCS1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99545076; called by muse, mutect2, varscan2
- SPRY3 | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 28/317 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100249271; called by muse, mutect2
- SRRM2 | c.5828G>T p.R1943L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV100070568; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.580A>G p.S194G | Missense Mutation (SNP) | VAF 9/73 reads (12%) | PolyPhen benign (0.006); catalogued as rs1315468045, COSV100082572; called by muse, mutect2, varscan2
- STK32B | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99285054; called by muse, mutect2, varscan2
- SULT1E1 | c.430A>T p.M144L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV99894862; called by muse, mutect2, varscan2
- TBC1D10A | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99304567; called by muse, mutect2, varscan2
- TDRD1 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV52587965, COSV99314379; called by muse, mutect2
- TLR8 | c.1942C>G p.L648V (on ENST00000218032 / NM_138636.5; = p.L666V on NM_016610.4) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV99486936; called by muse, mutect2, varscan2
- TMEM169 | c.616T>C p.Y206H | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV99824447; called by muse, mutect2, varscan2
- TMPRSS15 | c.587C>A p.T196K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99517519; called by muse, mutect2, varscan2
- TMPRSS3 | c.1298T>G p.V433G | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99367914; called by muse, mutect2, varscan2
- TPH2 | c.765C>A p.D255E | Missense Mutation (SNP) | VAF 55/382 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs1349614764, COSV100422001; called by muse, mutect2, varscan2
- TPR | c.5126C>G p.P1709R | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100823794; called by muse, mutect2
- TRAT1 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.23); catalogued as COSV55468735; called by muse, mutect2, varscan2
- TRERF1 | c.2746G>A p.V916M | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100550431; called by muse, mutect2, varscan2
- TRIP11 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99970533; called by muse, mutect2
- TTC26 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV100570948; called by muse, mutect2, varscan2
- TUBB4B | c.1276C>G p.Q426E | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.988); catalogued as COSV100457838; called by muse, mutect2
- UBR4 | c.1242G>T p.L414F | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100920664; called by muse, mutect2, varscan2
- ULBP3 | c.614G>T p.R205M | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100949615; called by muse, mutect2, varscan2
- UNC79 | c.7282G>T p.V2428L (on ENST00000393151 / NM_001346218.2; = p.V2251L on NM_020818.5) | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769787938, COSV99827017; called by muse, mutect2, varscan2
- USP29 | c.1634C>G p.T545S | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99517936; called by muse, mutect2
- USP47 | c.2009G>T p.R670L (on ENST00000399455 / NM_001372095.1; = p.R582L on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.462); catalogued as rs370810608, COSV100359383; called by muse, mutect2, varscan2
- VPS13B | c.6088A>G p.T2030A | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100661578; called by muse, mutect2, varscan2
- VPS18 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV99592423, COSV99592896; called by muse, mutect2, varscan2
- VWA3B | c.2458C>A p.L820M | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.339); catalogued as COSV101345992; called by muse, mutect2, varscan2
- WDR53 | c.959A>C p.N320T | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100218043; called by muse, mutect2
- ZBBX | c.2288G>T p.R763I | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV100283331, COSV100283696, COSV56799832; called by muse, mutect2, varscan2
- ZBTB46 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV55507716; called by muse, mutect2, varscan2
- ZC3H6 | c.3500G>T p.R1167I | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.202); catalogued as COSV100674494; called by muse, mutect2, varscan2
- ZCRB1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as rs1288153232; called by muse, mutect2
- ZFHX4 | c.9115G>T p.V3039F | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51496808, COSV51500069, COSV99264351; called by muse, mutect2
- ZNF234 | c.1709G>A p.C570Y | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755734972, COSV101468350; called by muse, mutect2, varscan2
- ZNF416 | c.481T>G p.C161G | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99543738; called by muse, mutect2, varscan2
- ZNF611 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs765175207, COSV100160178; called by muse, mutect2
- ZNF648 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs201927958, COSV100374509; called by muse, mutect2, varscan2
- BRD3 | c.832del p.R278Gfs*84 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | called by mutect2, pindel, varscan2
- CYP4F2 | c.1052dup p.E352Gfs*15 | Frame Shift Ins (INS) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- DOCK5 | c.248del p.G83Afs*25 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- FAM71B | c.296dup p.H99Qfs*38 | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- FCGBP | c.10558G>A p.A3520T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- IGHA2 | c.545C>A p.P182Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- IGHV1-24 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 66/304 reads (22%) | called by muse, mutect2, varscan2
- INTS14 | c.686C>T p.P229L (on ENST00000313182 / NM_001366360.2; = p.P150L on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF4 | c.102del p.T35Qfs*20 | Frame Shift Del (DEL) | VAF 40/186 reads (22%) | called by mutect2, varscan2
- SEC14L1 | c.293del p.Y98Lfs*35 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | called by mutect2, varscan2
- SMG6 | c.3859del p.A1287Pfs*42 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- TMEM184A | c.811_814+13del p.X271_splice | Splice Site (DEL) | VAF 14/91 reads (15%) | called by mutect2, pindel
- TTR | c.77del p.G26Vfs*7 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- UNG | c.455del p.G152Dfs*39 (on ENST00000242576 / NM_080911.3; = p.G143Dfs*39 on NM_003362.4) | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- AAR2 | c.591G>A p.E197= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV57924705; called by muse, mutect2, varscan2
- ABCC10 | c.3306A>C p.P1102= (on ENST00000372530 / NM_001198934.2; = p.P1074= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99767033; called by muse, mutect2, varscan2
- ABCC8 | c.1767G>A p.P589= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as rs550788491, COSV56848862; called by muse, mutect2, varscan2
- ADNP | c.2904T>C p.G968= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as COSV100823692; called by muse, mutect2
- AKR1D1 | c.672C>A p.T224= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV99652960; called by muse, mutect2, varscan2
- ALOX5 | c.1170G>T p.V390= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100980031; called by muse, mutect2, varscan2
- APLNR | c.690C>T p.G230= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- APOB | c.5784T>C p.Y1928= | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as COSV99264850; called by muse, mutect2
- C3orf20 | c.2586C>T p.A862= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV53787592; called by muse, mutect2, varscan2
- CACNA1C | c.3759C>A p.I1253= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100217580; called by muse, mutect2, varscan2
- CCKBR | c.789C>G p.V263= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100582864, COSV58101625; called by muse, mutect2, varscan2
- CDH10 | c.2121C>T p.N707= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs1293883738, COSV100050896, COSV52584655; called by muse, mutect2, varscan2
- CECR2 | c.933C>T p.S311= (on ENST00000342247 / NM_001290047.2; = p.S148= on NM_001290046.1) | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV99377576; called by muse, mutect2, varscan2
- CLCN5 | c.1632A>C p.T544= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as COSV100259995; called by muse, mutect2, varscan2
- CLSTN2 | c.1125G>A p.L375= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV71717663; called by muse, mutect2, varscan2
- DGKI | c.1677A>T p.R559= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99933425; called by muse, mutect2, varscan2
- DUSP10 | c.1269G>A p.L423= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV100100305; called by muse, mutect2, varscan2
- EGFR | c.873C>T p.C291= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs570790705, COSV51798564; called by muse, mutect2, varscan2
- ELMO1 | c.2133G>T p.P711= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as COSV100163964; called by muse, mutect2, varscan2
- EPCAM | c.195A>G p.K65= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99764101; called by muse, mutect2, varscan2
- FLG | c.10113C>T p.S3371= | Silent (SNP) | VAF 34/620 reads (5%) | catalogued as rs141599535, COSV100912231; called by muse, mutect2
- GALNT17 | c.1141C>A p.R381= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV100353306, COSV61160204; called by muse, mutect2, varscan2
- GRIN2B | c.4167C>T p.P1389= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as rs779633781, COSV101662993; called by muse, mutect2, varscan2
- GYPA | c.318G>T p.T106= | Silent (SNP) | VAF 69/172 reads (40%) | catalogued as COSV51618752, COSV51626553, COSV99301501; called by muse, mutect2, varscan2
- HEATR6 | c.1536C>T p.I512= | Silent (SNP) | VAF 19/224 reads (8%) | catalogued as COSV99482241; called by muse, mutect2
- HYAL4 | c.132A>G p.Q44= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV99772169; called by muse, mutect2, varscan2
- KCNH7 | c.1836C>T p.D612= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs781187609, COSV100035085; called by muse, mutect2, varscan2
- MINDY2 | c.1203C>T p.D401= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs754391768, COSV100376358; called by muse, mutect2, varscan2
- MYPN | c.876G>A p.V292= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs531434006, COSV100589799, COSV62732565; called by muse, mutect2, varscan2
- NLRP8 | c.2184G>A p.R728= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV99405070; called by muse, mutect2, varscan2
- NPC1L1 | c.837C>T p.G279= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs547747563, COSV99204553; called by muse, mutect2, varscan2
- NPY1R | c.429C>A p.I143= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as COSV99648643; called by muse, mutect2, varscan2
- OR1C1 | c.114C>A p.T38= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV101376210; called by muse, mutect2, varscan2
- OR2L3 | c.237G>A p.K79= | Silent (SNP) | VAF 111/387 reads (29%) | catalogued as COSV63455192, COSV63455980; called by muse, mutect2, varscan2
- OR4A5 | c.882T>A p.A294= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100157031; called by muse, mutect2
- OR4B1 | c.12A>G p.T4= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV100535551; called by muse, mutect2, varscan2
- OR52E4 | c.477C>A p.T159= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV100389204; called by muse, mutect2, varscan2
- OR5J2 | c.519T>G p.A173= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV100398968; called by muse, mutect2, varscan2
- PCDH10 | c.1542C>A p.T514= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV99993330; called by muse, mutect2, varscan2
- PCDH11Y | c.3588G>A p.Q1196= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV99291102; called by muse, mutect2, varscan2
- PCDHA7 | c.1182C>T p.P394= | Silent (SNP) | VAF 7/164 reads (4%) | catalogued as COSV65345355; called by muse, mutect2
- PCDHB9 | c.294T>C p.P98= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- PCDHGA12 | c.1897C>T p.L633= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV99339281; called by muse, mutect2, varscan2
- PEX5L | c.375C>A p.A125= | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as COSV99828375; called by muse, mutect2, varscan2
- PKHD1L1 | c.8049T>A p.I2683= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV101005901; called by muse, mutect2, varscan2
- PPM1E | c.993A>T p.T331= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100376097; called by muse, mutect2, varscan2
- PRDM16 | c.57T>C p.N19= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs1340436587, COSV99576187, COSV99576909; called by muse, mutect2, varscan2
- RFX1 | c.1872G>T p.V624= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99585967; called by muse, mutect2, varscan2
- RPL10A | c.150G>T p.S50= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV57689365; called by muse, mutect2, varscan2
- RTN4 | c.729C>T p.A243= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs202014771; called by muse, mutect2, varscan2
- SDK1 | c.6093G>A p.L2031= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs1290326585, COSV101269135; called by muse, mutect2, varscan2
- SEMA6D | c.2526A>G p.S842= (on ENST00000316364 / NM_153618.2; = p.S780= on NM_020858.2) | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV100316758; called by muse, mutect2
- SLC16A10 | c.744C>T p.G248= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1225129237, COSV100920849; called by muse, mutect2, varscan2
- SLC25A6 | c.450A>G p.T150= | Silent (SNP) | VAF 22/153 reads (14%) | catalogued as COSV101195440; called by muse, mutect2, varscan2
- SORCS3 | c.669C>A p.G223= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100864952; called by muse, mutect2, varscan2
- SPHKAP | c.2934C>A p.S978= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV60889744; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3132T>C p.D1044= | Silent (SNP) | VAF 23/163 reads (14%) | catalogued as COSV100561703; called by muse, mutect2, varscan2
- SVIL | c.732G>T p.R244= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100881175; called by muse, mutect2, varscan2
- TANGO2 | c.675G>A p.A225= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1299732711, COSV100530018, COSV59294914; called by muse, mutect2, varscan2
- TDRD5 | c.1326C>G p.L442= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99675924; called by muse, mutect2
- TMEM132D | c.780C>A p.S260= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV70604469, COSV70608955; called by muse, mutect2, varscan2
- TNC | c.300C>T p.F100= | Silent (SNP) | VAF 59/392 reads (15%) | catalogued as COSV100405464; called by muse, mutect2, varscan2
- TRMT6 | c.342G>A p.L114= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV99177543; called by muse, mutect2, varscan2
- UBR2 | c.3045A>G p.E1015= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100867404; called by muse, mutect2, varscan2
- URB2 | c.2115C>G p.A705= | Silent (SNP) | VAF 70/218 reads (32%) | catalogued as COSV99270971; called by muse, mutect2, varscan2
- USH2A | c.12834C>T p.P4278= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV56332450; called by muse, mutect2
- USH2A | c.3771A>C p.T1257= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV100232580; called by muse, mutect2, varscan2
- ZFHX4 | c.3336A>T p.S1112= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99260945; called by muse, mutect2
- ZNF563 | c.726A>G p.R242= | Silent (SNP) | VAF 10/214 reads (5%) | catalogued as COSV99536515; called by muse, mutect2
- ZNF83 | c.672G>C p.R224= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99991293; called by muse, mutect2
- ZSWIM2 | c.120T>A p.T40= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99720068; called by muse, mutect2, varscan2
- ADGRF2 | c.277-4354C>T | Intron (SNP) | VAF 8/129 reads (6%) | catalogued as COSV99731009; called by muse, mutect2
- C8A | c.*1G>A | 3'UTR (SNP) | VAF 4/36 reads (11%) | catalogued as rs1361617561, COSV100776470; called by muse, mutect2, varscan2
- CACNA1D | c.1220+686A>C | Intron (SNP) | VAF 10/67 reads (15%) | catalogued as COSV99857506; called by muse, mutect2, varscan2
- ITGB1 | c.2331+1234C>G | Intron (SNP) | VAF 9/140 reads (6%) | catalogued as COSV100171471; called by muse, mutect2
- MIR551B | n.51G>A | RNA (SNP) | VAF 24/130 reads (18%) | called by muse, mutect2, varscan2
- NXF5 | n.459C>G | RNA (SNP) | VAF 34/119 reads (29%) | catalogued as COSV99534257, COSV99534350; called by muse, mutect2, varscan2
- PPP2R1B | chr11:111737503 C>A | 3'Flank (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100232058; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-44452G>T | Intron (SNP) | VAF 41/127 reads (32%) | catalogued as COSV101043460; called by muse, mutect2, varscan2
- SNORD116-12 | n.64A>G | RNA (SNP) | VAF 19/95 reads (20%) | catalogued as rs750667066; called by muse, mutect2, varscan2
